CCDI case PBBTYR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a91c7a8f-4ff6-4df0-bb4a-118370ea933f

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.5 years (1,291 days).

Biospecimens (3 samples)
- Sample 0DHOGW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHOIY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHOJ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
